Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A75O, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A75O-01A (Primary Tumor).

Final Diagnosis:

A. C-D. Brain, left frontal mass #1, #2 and CUSA, biopsy: WHO grade III (of IV) fibrillary and gemistocytic astrocytoma (anaplastic astrocytoma).

B. Brain, left temporal cortex, biopsy: WHO grade III (of IV) fibrillary and gemistocytic astrocytoma (anaplastic astrocytoma).

Seen in consultation with

Interpreted by:

Report electronically signed by.

Transcribed by:

Preliminary Frozen Section Consultation:

A. Brain, left frontal mass #1, smears: Glioma. Hold over to classify and grade.

Intraoperative cytologic smears interpretation performed by:

Seen in consultation with

ICD-0-3

Astrocytoma, grade III
9401/3

Site ② Brain, supratentorial NOS
C71.0

JW 8/12/13

continued next page Page 1 of 2

MDA Discrepancy		✓

Source: NCI Genomic Data Commons file 23d95029-40ef-4fb3-9044-89408bdb3094 (TCGA-DB-A75O.CADF06CC-B405-4CFF-AB8D-92DA06CB345C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).